Somatic mutation profile of tumor specimen 0DK3EE from CCDI case PBBXSR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 16.3 years (5,948 days).
Specimen 0DK3EE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49f39b5f-d974-4c0c-a2b4-8cd1454fe7df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK3ER (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9662418d-7bfb-4b17-b2ae-ff33631160e1

The open-access MAF lists 37 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, 3'UTR 4, Intron 3, RNA 3, Nonsense Mutation 2, 5'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD3 | c.2863C>G p.P955A (on ENST00000297405 / NM_001363185.1; = p.P851A on NM_052900.3) | Missense Mutation (SNP) | VAF 497/1203 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.925); catalogued as COSV52152640; called by muse, mutect2, varscan2
- GUCY2C | c.2299C>T p.R767C | Missense Mutation (SNP) | VAF 394/1072 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1327537007; called by muse, mutect2, varscan2
- ITM2A | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 462/1264 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64811686; called by muse, mutect2, varscan2
- KRT82 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 203/493 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as rs139996519, COSV99233615; called by muse, mutect2, varscan2
- MRPL28 | c.284A>G p.D95G | Missense Mutation (SNP) | VAF 307/681 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.592); catalogued as rs754118448; called by muse, mutect2, varscan2
- MUC12 | c.5860C>G p.P1954A (on ENST00000379442; = p.P1811A on NM_001164462.1) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.55); catalogued as rs111685361, COSV65188428; called by mutect2, varscan2
- PCDHGA2 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 59/1449 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.563); catalogued as rs868424998; called by muse, mutect2
- PCLO | c.12836C>T p.A4279V | Missense Mutation (SNP) | VAF 162/2091 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.305); catalogued as rs753027344, COSV61625968; called by muse, mutect2
- PTCH1 | c.3058C>T p.Q1020* | Nonsense Mutation (SNP) | VAF 370/500 reads (74%) | catalogued as CM112677, COSV59474705; called by muse, mutect2, varscan2
- RUNX1 | c.887C>T p.T296M (on ENST00000344691 / NM_001001890.3; = p.T323M on NM_001754.5) | Missense Mutation (SNP) | VAF 259/594 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs1039736738, COSV100276757; called by muse, mutect2, varscan2
- BGN | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 338/916 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 42/1546 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CCDC138 | c.561A>G p.I187M | Missense Mutation (SNP) | VAF 38/1058 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CMYA5 | c.10957_10958insCCC p.V3653delinsAL | In Frame Ins (INS) | VAF 294/769 reads (38%) | called by mutect2, pindel, varscan2
- H2BC13 | c.127T>C p.Y43H | Missense Mutation (SNP) | VAF 481/1207 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PLXNA3 | c.200T>A p.V67D | Missense Mutation (SNP) | VAF 382/1064 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- PPP4R3A | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 42/1352 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SMPX | c.52A>G p.I18V | Missense Mutation (SNP) | VAF 461/1102 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- WDR5 | c.683A>G p.Y228C | Missense Mutation (SNP) | VAF 348/450 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZBTB10 | c.1366C>T p.R456* | Nonsense Mutation (SNP) | VAF 624/1324 reads (47%) | called by muse, mutect2, varscan2
- DNAH5 | c.3717C>T p.F1239= | Silent (SNP) | VAF 608/1384 reads (44%) | catalogued as COSV54226634; called by muse, varscan2
- GPR45 | c.1113G>A p.A371= | Silent (SNP) | VAF 507/1158 reads (44%) | catalogued as rs949071111, COSV51523431; called by muse, mutect2, varscan2
- OR11H4 | c.144C>T p.T48= | Silent (SNP) | VAF 379/799 reads (47%) | catalogued as COSV59560460; called by muse, mutect2, varscan2
- PDE6A | c.924G>A p.P308= | Silent (SNP) | VAF 156/390 reads (40%) | catalogued as rs369194532; called by muse, mutect2, varscan2
- REL | c.603A>G p.G201= | Silent (SNP) | VAF 449/1041 reads (43%) | called by muse, mutect2, varscan2
- SLC5A10 | c.684C>T p.Y228= | Silent (SNP) | VAF 339/721 reads (47%) | catalogued as rs544692412; called by muse, mutect2, varscan2
- AHDC1 | c.-46T>A | 5'UTR (SNP) | VAF 1361/1387 reads (98%) | called by muse, mutect2, varscan2
- ANO4 | c.558-30C>T | Intron (SNP) | VAF 138/328 reads (42%) | catalogued as rs1175888507; called by muse, mutect2, varscan2
- BAGE2 | n.129T>A | RNA (SNP) | VAF 180/1176 reads (15%) | called by muse, mutect2
- C15orf40 | c.*820_*821insGA | 3'UTR (INS) | VAF 7/76 reads (9%) | called by mutect2, pindel*
- HTATSF1 | c.*58G>A | 3'UTR (SNP) | VAF 160/335 reads (48%) | called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 27/565 reads (5%) | called by muse, mutect2
- MTRNR2L9 | n.6T>C | RNA (SNP) | VAF 227/541 reads (42%) | called by muse, mutect2, varscan2
- NFKB1 | c.157-55G>A | Intron (SNP) | VAF 196/487 reads (40%) | catalogued as rs1247561921; called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 23/238 reads (10%) | called by muse, varscan2
- UNK | c.*85A>G | 3'UTR (SNP) | VAF 176/409 reads (43%) | catalogued as rs1020761702, COSV52886076; called by muse, varscan2
- VLDLR | c.*49G>A | 3'UTR (SNP) | VAF 377/1191 reads (32%) | catalogued as rs199836483; called by muse, mutect2, varscan2
